Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4JX, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4JX-01A (Primary Tumor).

3:

Sex: F

ician:

Accession:

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) TOTAL THYROIDECTOMY: PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Right lobe

Multi-focal: No

Size = 4.0 cm

Extrathyroidal extension: Absent

Lymphovascular invasion: Absent

Resection Margins: Negative

Background Thyroid: Chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Parathyroid, negative for tumor (A7)

Lymph node, negative for tumor (0/1)

ICD-0-3
carcinoma, papillary thyroid 8260/3
Site: thyroid, nos c73.9

hw
10/4/12

(B) RIGHT PARATRACHEAL NODULE:

One lymph node, negative for tumor

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY - A total thyroidectomy specimen with markedly enlarged right thyroid lobe (7.0 x 3.0 x 3.0 cm), isthmus with pyramidal lobe (4.2 x 1.5 x 1.0 cm) and enlarged left lobe (5.0 x 2.0 x 2.5 cm). The gland is diffusely large with pale pink parenchyma suggestive of thyroiditis. Within the medial to inferior aspect of the right lobe anteriorly, the parenchyma is firm, white, corresponding to a tumor (4.0 x 3.0 x 2.6 cm) confined to the thyroid.

SECTION CODE: A1, representative left superior lobe with well-defined tan nodule; A2-A4, additional sections of right lobe, middle and inferior portions; A5, A6, sections of isthmus and possible lymph nodes; A7, two well-circumscribed, round nodules of right lobe; A8-A14, sections of right lobe from superior to inferior with tumor.

(B) RIGHT PARATRACHEAL NODULE - A single dark red nodule measuring 0.8 x 0.3 x 0.2 cm. Entirely submitted in cassette B.

CLINICAL HISTORY

None given.

SNOMED CODES

T-B6000, M-80503, M-B0630,

"Some tests reported here may have been developed and performance characteristics determined by These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Surgical Pathology Report

File under: Pathology

Diagnostic Discrepancy		☒
Metastatic Discrepancy		☒

10/4/12

Source: NCI Genomic Data Commons file b20caa60-e1e3-4b41-a8ce-a32e0ab9e718 (TCGA-EL-A4JX.1B5E8571-DB8F-49A3-85C0-66FE037DC1E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).